CCDI case PBCGVW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/1e0c29fe-6fdb-4446-8b78-4d30a8d9d372

Demographics
Sex at birth: male.

Diagnoses (1)
1. Angiomatoid fibrous histiocytoma: ICD-O-3 morphology code: 8836/1; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 7.3 years (2,669 days).

Biospecimens (3 samples)
- Sample 0DRO3L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRO3T: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRO3X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
